Gene-level copy-number profile of tumor specimen TCGA-AO-A03N-01B from TCGA case TCGA-AO-A03N, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.7 years (21,816 days).
Specimen TCGA-AO-A03N-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.b721638f-668e-4118-b704-04e85f308aa3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A03N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7e5e23ed-7693-49c7-9225-7588fadc8974

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 386; copy number 2: 14,273; copy number 3: 25,215; copy number 4: 9,441; copy number 5: 5,604; copy number 6: 2,618; copy number 7: 2,086; copy number 8: 62; copy number 10: 65; copy number 11: 11; copy number 12: 58.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A03N-01B-11D-A10L-01): tumor purity 0.63, ploidy 3.16, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,231 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:239,052,748–240,654,625, 24 genes, copy number 7: AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5.
- chr10:22,787,393–22,787,499, 1 gene, copy number 7: RNU6-413P.
- chr10:25,174,802–25,602,229, 1 gene, copy number 7 (within-gene range 2–7): GPR158.
- chr10:25,393,557–25,933,710, 7 genes, copy number 7: RN7SKP220, GPN3P1, LINC00836, HIRAP1, RNA5SP306, RNU6-632P, AL358612.1.
- chr10:71,396,920–71,815,947, 1 gene, copy number 7 (within-gene range 5–7): CDH23.
- chr10:71,711,701–73,740,823, 79 genes, copy number 7 (broad region; genes not listed).
- chr10:78,068,623–78,697,022, 10 genes, copy number 7: GNAI2P2, AL731555.1, AC012560.1, LINC00595, AC010163.3, AC010163.1, AC010163.2, SNORA71, AL583852.1, AC016820.1.
- chr10:80,649,797–81,875,133, 7 genes, copy number 11: LINC02655, RPS7P9, AC027673.1, FARSBP1, WARS2P1, RPA2P2, AL096706.1.
- chr10:83,911,654–83,912,922, 1 gene, copy number 7: AL390786.1.
- chr10:122,374,696–125,166,937, 58 genes, copy number 12 (within-gene range 6–12): PLEKHA1, MIR3941, BX842242.1, ARMS2, HTRA1, DMBT1, AL603764.1, AL603764.2, C10orf120, DMBT1L1, CUZD1, AC073585.1, FAM24B, C10orf88B, FAM24A, C10orf88, PSTK, IKZF5, ACADSB, HMX3, HMX2, BUB3, RPS26P39, AL160290.2, LINC02641, AL160290.1, AL357127.2, AL357127.1, GPR26, CPXM2, AC009987.1, AC068058.1, BX469938.1, YBX2P1, AL683842.1, CHST15, OAT, NKX1-2, AL445237.1, LHPP, RPS10P18, AC068896.1, FAM53B, AL513190.1, FAM53B-AS1, EEF1AKMT2, Y_RNA, ABRAXAS2, Y_RNA, NPM1P31, AL731577.2, ZRANB1, AL731577.1, CTBP2, AL731571.1, MIR4296, AL157888.1, MRPS21P6.
- chr14:21,918,188–22,509,406, 82 genes, copy number 7 (broad region; genes not listed).
- chr14:30,370,108–34,561,298, 67 genes, copy number 7 (broad region; genes not listed).
- chr14:34,568,689–34,569,129, 1 gene, copy number 7: RPS19P3.
- chr14:36,647,083–37,172,606, 6 genes, copy number 7 (within-gene range 5–7): AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503.
- chr14:37,197,913–39,432,500, 38 genes, copy number 7–11 (within-gene range 5–11): MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1, AL357094.1, KRT8P1, LINC00639, AL132994.1, AL132994.2, Y_RNA, SEC23A, AL109628.1, SEC23A-AS1, PPIAP4, GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2, GLRX5P3, COILP1, FBXO33.
- chr14:40,267,283–40,348,331, 1 gene, copy number 8: AL049828.2.
- chr14:41,514,972–45,290,386, 46 genes, copy number 8: AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1, AL445074.1, AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1, AL163153.1, TUBBP3, HNRNPUP1, AL583809.1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9.
- chr14:45,891,087–46,651,781, 2 genes, copy number 8 (within-gene range 5–8): LINC00871, RPL10L.
- chr14:46,960,423–46,997,174, 2 genes, copy number 8: AL359951.1, RPA2P1.
- chr14:49,373,966–55,796,731, 168 genes, copy number 7 (broad region; genes not listed).
- chr14:56,117,814–57,493,867, 26 genes, copy number 7 (within-gene range 2–7): PELI2, AL355073.1, AL355073.2, LINC02284, TMEM260, AL355103.1, AL161757.2, AL161757.5, AL161757.1, AL161757.3, OTX2, OTX2-AS1, AL161757.4, RN7SL461P, RNU6-1204P, AL137100.3, RPL3P3, AL137100.1, AL137100.2, AL391152.1, EXOC5, AP5M1, AL355834.2, AL355834.1, NAA30, CCDC198.
- chr14:57,578,409–57,631,162, 2 genes, copy number 7: AL161804.1, AL136520.1.
- chr14:58,633,967–59,870,776, 14 genes, copy number 7 (within-gene range 5–7): DACT1, LINC01500, AL049873.1, AL049873.2, AKR1B1P5, PPIAP5, DAAM1, GPR135, L3HYPDH, AL121694.1, JKAMP, CCDC175, RTN1, MIR5586.
- chr14:60,245,752–65,222,443, 103 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr16:11,555–48,746,318, 1,484 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 386. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
